Gene-level copy-number profile of tumor specimen TCGA-85-8048-01A from TCGA case TCGA-85-8048, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.7 years (22,907 days).
Specimen TCGA-85-8048-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d7601961-1b2b-433c-ab75-65f48c6c70fb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8048-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9027af5c-8be6-4675-8ad0-c3ae61a9e65e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 131; copy number 1: 19,307; copy number 2: 32,752; copy number 3: 5,015; copy number 4: 876; copy number 5: 1,088; copy number 6: 177; copy number 7: 206; copy number 8: 243; copy number 9: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8048-01A-11D-2243-01): tumor purity 0.18, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 131 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:76,886,029–78,544,269, 26 genes (within-gene range 0–1): AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6, CCNI, RPL7P17, AC104771.1, RNU6-1187P, CCNG2, AC008638.3, AC008638.2, AC008638.1, AC092674.1, CXCL13, AC104701.1, CNOT6L, MRPL1, AC112225.1, AC114801.2, HMGB1P44, HNRNPA1P56, AC114801.1, AC114801.3, FRAS1, SERBP1P5.
- chr14:21,903,077–22,535,614, 105 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,735 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:161,426,427–189,897,276, 440 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr5:58,198–35,827,018, 542 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:70,972–5,563,902, 125 genes, copy number 5–9 (broad region; genes not listed).
- chr7:68,149,548–68,724,048, 5 genes, copy number 5: AC093655.1, AC093655.2, MTND4P3, AC004910.1, RNA5SP231.
- chr8:34,784,028–35,796,550, 7 genes, copy number 5 (within-gene range 2–5): LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1.
- chr8:38,176,533–38,996,824, 26 genes, copy number 6: BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2.
- chr8:39,018,615–39,018,683, 1 gene, copy number 6: SNORD38D.
- chr11:68,980,021–72,434,680, 121 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr19:27,638,483–37,469,275, 327 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:42,924,132–45,645,602, 141 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,307. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
